Somatic mutation profile of tumor specimen MP2PRT-PAVGDD-TMP1-A (aliquot MP2PRT-PAVGDD-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGDD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,523 days).
Specimen MP2PRT-PAVGDD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efb668db-33d0-49e1-a9cc-72bf2b72f45f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGDD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGDD-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06e1e445-e6e1-4fe7-9cc9-115e2ac0e21d

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 1, Silent 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSTR5 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs768617604; called by muse, mutect2, varscan2
- PRDM14 | c.1325A>G p.E442G | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRDV2 | c.326_345delinsTCCCTGT p.Y109Ffs*? | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by pindel, varscan2*
- XYLB | c.676_677insGAGGCAGG p.D226Gfs*19 | Frame Shift Ins (INS) | VAF 42/243 reads (17%) | called by pindel, varscan2*
- GOLM1 | c.582C>T p.N194= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as rs779822821, COSV57413606; called by muse, mutect2, varscan2
- XIST | n.7381T>C | RNA (SNP) | VAF 12/284 reads (4%) | catalogued as rs1391392148; called by muse, mutect2
